MMRF case MMRF_2499 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/20805efb-a12e-4351-b303-b57bcf7653f5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.1 years (20,130 days); ISS stage: I; Days to last known disease status: 723 days (2.0 years); Days to last follow up: 723 days (2.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 58 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 28 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 58 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 140 days; Days to treatment end: 140 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 0): M Protein 3.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 42.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.362 mg/dL; Immunoglobulin G 45.9 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 301 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 9.1 g/dL; Glucose 4.51 mmol/L.
- Day 100 (ECOG 0): M Protein 3.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 3.13 µg/mL; Lactate Dehydrogenase 4.73 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 1.83 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 4.51 mmol/L.
- Day 198 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.869 mg/dL; Hemoglobin 6.51 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.05 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 4.68 mmol/L.
- Day 240 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.925 mg/dL; Immunoglobulin G 7.63 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.54 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 60.1 µmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 5.06 mmol/L.
- Day 304 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 1.12 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.18 mmol/L.
- Day 408 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.79 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 4.9 mmol/L.
- Day 560 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.86 g/L; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 632 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.74 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.06 mmol/L.
- Day 723 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.91 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 1.01 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day 0: Weight: 103 kg; Height: 154 cm.

Biospecimens (2 samples)
- Sample MMRF_2499_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2499_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
